Gene-level copy-number profile of tumor specimen TCGA-CN-5366-01A from TCGA case TCGA-CN-5366, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 51.8 years (18,904 days).
Specimen TCGA-CN-5366-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.9020380d-74f5-417a-8a62-6c16147d914c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CN-5366-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/99129a83-5298-4bc6-8947-54bc5ac0be91

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 13; copy number 2: 8,864; copy number 3: 26,298; copy number 4: 16,176; copy number 5: 2,381; copy number 6: 2,301; copy number 7: 1,944; copy number 8: 1,713; copy number 11: 52; copy number 13: 62; copy number 14: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CN-5366-01A-01D-1432-01): tumor purity 0.25, ploidy 3.5, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,782 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:147,844,123–198,222,513, 907 genes, copy number 7 (broad region; genes not listed).
- chr7:38,253,380–38,318,861, 11 genes, copy number 14: TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9.
- chr8:74,891,151–133,134,903, 818 genes, copy number 7–11 (broad region; genes not listed).
- chr8:135,859,369–137,092,183, 1 gene, copy number 7 (within-gene range 6–7): LINC02055.
- chr8:137,105,352–145,066,685, 222 genes, copy number 7 (broad region; genes not listed).
- chr11:69,909,184–71,863,658, 62 genes, copy number 13 (broad region; genes not listed).
- chr14:21,962,819–22,482,959, 48 genes, copy number 11 (within-gene range 3–11): AC245505.1, TRAV12-3, TRAV8-6, TRAV16, TRAV17, TRAV18, TRAV19, AC245505.2, TRAV20, TRAV21, AC245505.3, TRAV22, TRAV23DV6, TRDV1, TRAV24, TRAV25, TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3.
- chr14:32,271,857–106,875,071, 1,713 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 13. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
